Surgical pathology report (de-identified scan), TCGA case TCGA-20-1684, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-20-1684-01A (Primary Tumor).

[page 1 of 5]
TCGA-20-1684

Age:

Sex:

Clinical History/Diagnosis: Pelvic mass.

Source of Specimen(s):

- 1: Cytology
- 2: Right Fallopian Tube +/- Ovary
- 3: Left Fallopian Tube +/- Ovary
- 4: Uterus with or without Cervix
- 5: nodule, pelvic peritoneal
- 6: Omentum, resection other than for tumor
- 7: Right hepatic peritoneum node
- 8: Right periaortic node
- 9: Right pelvic Lymph Node
- 10: Appendix
- 11: nodule, epiploic
- 12: nodule, portahepatis

Gross Description:

Received in twelve parts.

Source of tissue: 1. Cytology.

Source of tissue: 2. Labeled #2, 3right tube and ovary4

Frozen Section Diagnosis: 2FS SEROUS CARCINOMA.

Gross description: Received fresh labeled patient name and medical number, right tube and ovary4 consists of a 394 gram, 14 x 8 x 5.5 cm tortuous, cystic, tan-pink, hemorrhagic, nodular ovarian mass with an attached 7.5 x 1 cm fallopian tube with fimbriated end that contains a 2 x 1.8 x 1.8 cm pink-tan, hemorrhagic nodular mass at the fimbriated end. There are multiple paratubal cysts ranging from <0.1 cm up to 0.2 cm. The specimen is inked green, and sectioning of the ovary reveals a large, tan, slightly hemorrhagic solid to friable papillary mass with multiple cysts ranging from 0.3 cm up to 1.5 cm. A portion of the mass is frozen for frozen section diagnosis. The mass does grossly appear to extend through the capsule. Sectioning of the fallopian tube reveals tan-pink, hemorrhagic cut surfaces with a patent lumen. Representative sections are submitted as designated for microscopic evaluation.

Designation of sections: 2FS frozen section. 2A extension through capsule. 2B-2F random sections. Please note that cassette 2E contains mass and cysts. 2G mass at fimbriated end. 2H bisected fimbriated end. 2I cross sections of fallopian tube.

[page 2 of 5]
Source of tissue: 3. Labeled #3, 3left tube and ovary4

Gross description: Received fresh labeled patient name and medical number, left tube and ovary4 consists of a 5 x 0.7 cm pink-tan, hemorrhagic fallopian tube with fimbriated end with multiple paratubal cysts ranging from 0.2 cm up to 1.5 cm with the largest located at the fimbriated end and filled with a pale-yellow, creamy fluid. Attached to the fallopian tube is a 4 x 2 x 1 cm pale-yellow, slightly hemorrhagic nodular and cerebriform ovary. Sectioning of the fallopian tube reveals tan-pink cut surfaces with a patent lumen. Sectioning of the ovary reveals a 2 x 1.5 x 0.7 cm cyst filled with a red-brown, hemorrhagic fluid and a 1 x 1 x 0.3 cm cyst also filled with red-brown, hemorrhagic fluid. There are two nodules on the serosa of the ovary measuring 0.6 x 0.5 x 0.2 cm and 0.6 x 0.5 x 0.3 cm. Representative sections are submitted as designated for microscopic evaluation.

Designation of sections: 3A bisected fimbriated end. 3B cross sections of fallopian tube. 3C cross sections of ovary with cysts. 3D nodules on ovary.

Source of tissue: 4. Labeled #4, 3uterus and cervix4

Gross description: Received fresh labeled patient name and medical number, uterus and cervix4 consists of a 189 gram, 7 x 6 x 5 cm previously opened uterus and attached cervix 4 x 3.5 cm. The serosal surface is pink-tan, smooth, and mildly hemorrhagic. Exocervix is pale yellow, smooth and hemorrhagic with a 1 cm patent os. The endocervix is pale yellow and trabeculated with a pale yellow mucoid material. The myometrium is tan-pink, trabeculated and averages 2 cm with two well-circumscribed nodules 1 x 0.6 cm and 1.3 x 0.8 cm. The endometrium is pink, tan, hemorrhagic, somewhat friable and averages 0.5 cm. Sectioning reveals tan-pink cut surfaces. Representative sections are submitted as designated for microscopic evaluation.

Designation of sections: 4A anterior cervix. 4B posterior cervix. 4C-4D anterior full thickness. 4E-4F posterior full thickness. 4G nodules.

Source of tissue: 5. Labeled #5, 3pelvic peritoneal nodules4

Gross description: Received fresh labeled patient name and medical number, pelvic peritoneal nodules4 consists of two portions of yellow lobulated and hemorrhagic, firm fat 0.7 x 0.7 x 0.3 cm and 1.1 x 0.9 x 0.3 cm. Entirely submitted in cassette 5A for microscopic evaluation.

Source of tissue: 6. Labeled #6, 3omentum4

[page 3 of 5]
Gross description: Received fresh labeled patient name and medical number, omentum4 consists of a 45 x 11 x 1.5 cm portion of omentum. Sectioning reveals yellow lobulated, mildly hemorrhagic cut surfaces. No masses are grossly identified. Representative sections are submitted in cassettes 6A-6D for microscopic evaluation.

Source of tissue: 7. Labeled #7, 3right hepatic peritoneum nodule4

Gross description: Received fresh labeled patient name and medical number, right hepatic peritoneum nodule4 consists of a 3 x 1.5 x 0.3 cm portion of yellow lobulated, hemorrhagic, soft to nodular tissue. Sectioning reveals yellow lobulated and hemorrhagic cut surfaces with two nodules measuring 0.4 x 0.3 x 0.2 cm and 0.4 x 0.4 x 0.2 cm. Entirely submitted in cassettes 7A-7D for microscopic evaluation.

Source of tissue: 8. Labeled #8, 3right periaortic node4

Gross description: Received fresh labeled patient name and medical number, right periaortic node4 consists of a 5 x 2 x 0.7 cm portion of yellow lobulated, hemorrhagic fat. A 4 x 1 x 0.4 cm yellow-tan hemorrhagic lymph node is dissected out of the fat and bisected revealing tan-yellow cut surfaces. Entirely submitted in cassette 8A for microscopic evaluation.

Source of tissue: 9. Labeled #9, 3right pelvic lymph nodes4

Gross description: Received fresh labeled patient name and medical number, right pelvic lymph nodes4 consists of a 7.5 x 5 x 2 cm aggregate of yellow lobulated and hemorrhagic fat. Multiple lymph nodes are dissected out of the fat ranging from 0.3 cm up to 2.5 cm. Representative sections are submitted in cassettes 9A-9C for microscopic evaluation.

Source of tissue: 10. Labeled #10, 3appendix4

Gross description: Received fresh labeled patient name and medical number, appendix4 consists of a 6.5 x 0.7 cm appendix with attached yellow lobulated and hemorrhagic mesoappendix. The serosal surface is pink-tan to dark-red and mildly hemorrhagic with no grossly identifiable defects. The specimen is sectioned a wall thickness averaging 0.3 cm. A luminal diameter averaging 0.2 cm and a tan, velvety mucosa. Representative sections are submitted as designated for microscopic evaluation.

Designation of sections: 10A proximal and distal ends. 10B cross sections.

Source of tissue: 11. Labeled #11, 3epiploic nodule4

[page 4 of 5]
Gross description: Received fresh labeled patient name and medical number, epiploic nodule4 consists of a 1 x 0.7 x 0.3 cm pink-tan, firm nodule. Entirely submitted in cassette 11A for microscopic evaluation.

Source of tissue: 12. Labeled #12, 3portohepatic nodule4

Gross description: Received fresh labeled patient name and medical number, portohepatic nodule4 consists of a 0.8 x 0.5 x 0.2 cm portion of dark-red, hemorrhagic to tan, firm tissue. Entirely submitted in cassette 12A for microscopic evaluation.

Final Diagnosis:

1. Cytology.

2. Right tube and ovary, excision:

- Serous adenocarcinoma, grade III, 14.0 cm, involving ovary and fallopian tube.
- Angiolymphatic invasion is not identified.

3. Left tube and ovary, excision:

- Serous adenocarcinoma of the ovary, 0.6 cm.
- Fallopian tube with benign paratubal cysts, No tumor seen.
- Simple ovarian cyst.

4. Uterus and cervix, hysterectomy:

- Uterus with stromal hyperplasia.
- Leiomyoma.
- Cervix and low uterine segment with no evidence of disease.
- No tumor seen.

5. Pelvic peritoneal nodules, excision:

- Metastatic serous adenocarcinoma.

6. Omentum, resection:

- Adipose tissue with no tumor seen.

7. Right hepatic peritoneum nodule, excision:

- Metastatic serous adenocarcinoma.

8. Right periaortic lymph node, excision:

- Metastatic carcinoma in one lymph node (1/1).

9. Right pelvic lymph nodes, excision:

- No tumor seen in nine lymph nodes (0/9).

[page 5 of 5]
10. Appendix, appendectomy:
- Appendix; no tumor seen.

11. Epiploic nodule, excision:
- Metastatic serous adenocarcinoma.

12. Porto-hepatic nodule, excision:
- Metastatic serous adenocarcinoma.

Source: NCI Genomic Data Commons file b7cbf95b-dc7e-4056-9a85-a9de11bfd44b (TCGA-20-1684.3CE61823-9E89-424F-9CE2-A8987420B2A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).